Surgical pathology report (de-identified scan), TCGA case TCGA-ER-A3ET, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Pittsburgh, specimen TCGA-ER-A3ET-06A (Metastatic).

FINAL DIAGNOSIS:

SOFT TISSUE, VULVA, MELANOMA, RESECTION -

METASTATIC MELANOMA IN SOFT TISSUE EXTENDING TO SOME SOFT TISSUE MARGINS.

Collection Date:

COMMENT:

Refer to

, (and in

BRAF mutation was not identified).

TIPTA Discrepancy		

ICD-0-3

Melanoma, NOS 8720/3

CQCF Site: Subcutaneous tissue, NOS C49.9

Path Vulva, NOS C51.9

11/14/11

Source: NCI Genomic Data Commons file 82df3ce8-7ae0-47cd-bb3c-8087294235a7 (TCGA-ER-A3ET.49CF1653-1EE3-4C4C-B79D-1DEC59490210.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).